Surgical pathology report (de-identified scan), TCGA case TCGA-EC-A1QX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Asterand, specimen TCGA-EC-A1QX-01A (Primary Tumor).

ICD-0-3

adenocarcinoma, endometrioid, NOS 8384/3

Site: Endometrium C54.1

for 4/12/11

Procurement Date Laterality: NA

Path Report: UTERUS TISSUE CHECKLIST

Specimen type: Hysterectomy, bilateral salpingo-oophorectomy

Tumor site: Endometrium

Tumor size: 0 x 0 x 0 cm

Histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Greater than 1/2 myometrium

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Extent of myometrial invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Grade 3 endometrioid adenocarcinoma

Crite. la	Yes	No

Source: NCI Genomic Data Commons file 07d5ed94-182a-4228-90d7-6deefc5064aa (TCGA-EC-A1QX.0C3EABFA-0F72-47C9-9A8B-6B14F2CD2D12.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).